Gene-level copy-number profile of tumor specimen TARGET-20-PALGKX-09A from TARGET case TARGET-20-PALGKX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,723 days).
Specimen TARGET-20-PALGKX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.8ebb3928-8c17-54fc-b566-9801057a9ee1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PALGKX-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate.
https://portal.gdc.cancer.gov/files/1e0fdd3e-f72e-4b2e-b461-1224643d8073

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 963; copy number 2: 57,364; copy number 3: 1,209; copy number 4: 82; copy number 5: 71; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 73 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 2–5): MALLP2, AC244205.1.
- chr2:88,857,161–89,986,702, 69 genes, copy number 5 (broad region; genes not listed).
- chr20:1,561,385–1,620,061, 2 genes, copy number 14 (within-gene range 2–14): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 963. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
